FM case AD15981 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/1c203421-732d-41ac-a536-d663ee42334f

Male, 86.0 years: diagnosis not reported by GDC; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
